Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7250, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7250-01A (Primary Tumor).

[page 1 of 2]
Received: [REDACTED]

Pathologist: [REDACTED]

Accession: [REDACTED]

Case type: [REDACTED]

**** Case imported from legacy computer system. The format of this report does not match the original case. ****

**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) CERVICAL ESOPHAGEAL, CIRCUMFERENTIAL:

Squamous mucosa, no tumor present.

(B) TOTAL LARYNGECTOMY, PHARYNGECTOMY, BILATERAL NECK DISSECTION AND SUBTOTAL THYROIDECTOMY:

INVASIVE WELL-DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH PAPILLARY FEATURES OF THE LEFT PYRIFORM SINUS TUMOR (4.0 X 2.5 X 2.0 CM) WITH PERINEURAL INVASION PRESENT.

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA OF THE RIGHT SUPRAGLOTTIC TUMOR (3.0 X 1.5 X 1.0 CM).

LEFT NECK DISSECTION:

Twenty-eight lymph nodes, no tumor present (0/28).

RIGHT NECK DISSECTION:

Twenty lymph nodes, no tumor present (0/20).

Thyroid, no tumor present.

GROSS DESCRIPTION

(A) CERVICAL ESOPHAGEAL, CIRCUMFERENTIAL - A circular, soft tissue fragment measuring 1.5 x 1.0 x 0.3 cm. The entire specimen is submitted for frozen section as FSA. [REDACTED]

*FS/DX: CERVICAL ESOPHAGEAL MARGIN, NO TUMOR PRESENT. [REDACTED]

(B) TOTAL LARYNGECTOMY, PHARYNGECTOMY, BILATERAL NECK DISSECTION AND SUBTOTAL THYROIDECTOMY - A product of total laryngectomy and bilateral neck dissection with overall measurements of 11.0 x 10.0 x 4.5 cm. On sectioning a light-tan, slightly fungating and irregular lesion located mainly on the right supraglottic region and measuring 3.0 x 1.5 x 1.0 cm is noted. The lesion does not cross the middle line and is not connected grossly to the main left pyriform sinus tumor. The left pyriform sinus lesion measures 4.0 x 2.5 x 2.0 cm and extends to the left supraglottic larynx with an area of ulceration. The tumor does not extend to the left vocal cord and does not cross the midline grossly. The tumor is mainly fungating, light-tan and firm. The tumor is submitted entirely from right to left under B10-B19, sequential section from right to left on the right side. B19, B20, midline; B21-B29, sequential sections of the left supraglottic and pyriform sinus tumor; B30-B32, additional tumor sections; B33, thyroid; B34-B43, left neck dissection: B34-B36, 4 lymph nodes per cassette; B37-B41, 2 lymph nodes per cassette; B42, 3 lymph nodes; B43, 6 lymph nodes; B44-B53, right neck dissection, B44, 4 lymph nodes; B45, 4 lymph nodes; B46, 4 lymph nodes; B47, 4 lymph nodes; B48-B52, a single lymph node bisected per cassette; B53, possible lymph

[page 2 of 2]
[REDACTED]

node. B1-B9=margins of resection; B1-B3=9 to 12 o'clock; B4-B5, 12 to 3 o'clock; B6-B7, 3 to 6 o'clock; B8-B9, 6 to 9 o'clock. [REDACTED]

*FS/DX: TOTAL LARYNGOESOPHAGECTOMY, MARGIN OF RESECTION, FSBI-FBS9: FREE OF TUMOR. [REDACTED]

SNOMED CODES

M-80703 T-24100

Source: NCI Genomic Data Commons file f08f1376-613d-44ed-8f42-11c7759e5a6e (TCGA-CV-7250.00037EAC-1AB2-45FF-869A-E6A7C6580A1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).